Somatic mutation profile of tumor specimen TCGA-Z6-A8JD-01A (aliquot TCGA-Z6-A8JD-01A-11D-A36J-09) from TCGA case TCGA-Z6-A8JD, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.5 years (19,523 days).
Specimen TCGA-Z6-A8JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59365979-1bbb-48aa-aaf6-332cfc6abed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z6-A8JD-10A (Blood Derived Normal), aliquot TCGA-Z6-A8JD-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f4640ab-8f6a-40e5-afbd-061f7f37073e

The open-access MAF lists 205 somatic variants for this specimen: 149 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 49, Nonsense Mutation 13, Frame Shift Del 5, RNA 4, Splice Site 3, Splice Region 2, Intron 1, 5'UTR 1, Nonstop Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD12 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1411654806; called by muse, mutect2, varscan2
- ACOX2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs940877931, COSV57148962; called by muse, mutect2, varscan2
- AGPS | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as COSV99931170; called by muse, mutect2, varscan2
- ANKRD11 | c.3971C>G p.S1324C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV99969733, COSV99970167; called by muse, mutect2, varscan2
- ARL10 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59990152; called by muse, mutect2, varscan2
- ATE1 | c.852C>G p.F284L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1235159197; called by muse, mutect2, varscan2
- BMPR1A | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs199907158, COSV64409837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C16orf89 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1481746384; called by muse, mutect2, varscan2
- CAPN15 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.118); catalogued as COSV99562776; called by muse, mutect2, varscan2
- CIT | c.5852G>A p.R1951Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.805); catalogued as rs371376893; called by muse, mutect2, varscan2
- CLEC14A | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as rs780657376; called by muse, mutect2, varscan2
- CYTIP | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs370374268; called by muse, mutect2
- DLGAP5 | c.813G>C p.L271F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs760482885; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV100668741, COSV100668860; called by muse, mutect2, varscan2
- EFR3A | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as COSV54455428; called by muse, mutect2, varscan2
- ESRRA | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs45585533; called by muse, mutect2, varscan2
- FANCA | c.2818C>A p.Q940K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59796287; called by muse, mutect2, varscan2
- FUT10 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59450852; called by muse, mutect2
- GRM3 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100862181; called by muse, mutect2
- GTPBP4 | c.1700G>C p.S567T | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.468); catalogued as COSV52987020; called by muse, mutect2, varscan2
- GYS1 | c.1065G>T p.V355= | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as COSV54404077; called by muse, mutect2, varscan2
- HBA2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs281864876; called by muse, mutect2, varscan2
- IDE | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56422143; called by muse, mutect2, varscan2
- KIF7 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99177599; called by muse, mutect2, varscan2
- KRT81 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV59810184; called by muse, mutect2, varscan2
- LHX4 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as COSV55378658; called by muse, mutect2, varscan2
- LRFN5 | c.277C>G p.H93D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.281); catalogued as COSV99984077; called by muse, mutect2, varscan2
- MAGI1 | c.3920C>A p.A1307E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.066); catalogued as COSV104401237; called by muse, mutect2, varscan2
- MAP3K20 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs761040219; called by muse, mutect2, varscan2
- MGAM | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs369519766; called by muse, mutect2
- MYH6 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV100676913; called by muse, mutect2, varscan2
- NOP2 | c.1774C>T p.P592S (on ENST00000322166 / NM_001258308.2; = p.P588S on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs765511648; called by muse, mutect2
- NTM | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs758413842, COSV66198956; called by muse, mutect2, varscan2
- ODF2 | c.697G>A p.G233R (on ENST00000434106 / NM_153433.2; = p.G209R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV100654479, COSV100654886; called by muse, mutect2, varscan2
- OR10A6 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV59165202; called by muse, mutect2, varscan2
- OR8I2 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV100136265, COSV56168115; called by muse, mutect2, varscan2
- PCM1 | c.1357G>C p.V453L | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.178); catalogued as rs957724175; called by muse, mutect2, varscan2
- PFDN1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs371310256; called by muse, mutect2, varscan2
- PI4KA | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs371865226; called by muse, mutect2, varscan2
- PROX1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.5); catalogued as rs765586199; called by muse, mutect2, varscan2
- PTPN21 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112928496, COSV60850408; called by muse, mutect2, varscan2
- RALGAPA1 | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51877324; called by muse, mutect2, varscan2
- RIPOR1 | c.2437C>T p.P813S (on ENST00000379312 / NM_001193522.2; = p.P809S on NM_024519.4) | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV50225140; called by muse, mutect2, varscan2
- RPL3 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs1328546171, COSV99335141; called by muse, mutect2
- RYR3 | c.8828C>G p.S2943* (on ENST00000389232; = p.S2944* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV66776078; called by muse, mutect2, varscan2
- SESN3 | c.1478G>T p.*493Lext*18 | Nonstop Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99565198; called by muse, mutect2, varscan2
- SLC4A9 | c.1439G>A p.R480H (on ENST00000507527 / NM_001258428.2; = p.R456H on NM_031467.3) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs372321175; called by muse, mutect2, varscan2
- SWAP70 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs1210479901, COSV100013670; called by muse, mutect2, varscan2
- SYDE2 | c.3313G>C p.E1105Q | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100415547; called by muse, mutect2, varscan2
- UNC13D | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs866171293; called by muse, mutect2, varscan2
- WARS1 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs952755077; called by muse, mutect2, varscan2
- WDFY3 | c.4620G>C p.M1540I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99883350; called by muse, mutect2
- ZFP14 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751461218; called by muse, mutect2
- ZMYM6 | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as rs748753112, COSV64121067; called by muse, mutect2, varscan2
- ZNF281 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1402446389; called by muse, mutect2, varscan2
- ZNF676 | c.1213G>T p.A405S (on ENST00000650058; = p.A373S on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV68092982; called by muse, varscan2
- ZNF91 | c.1676C>G p.S559* | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | catalogued as COSV100322327; called by muse, mutect2, varscan2
- ACTR10 | c.690A>C p.K230N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- AHNAK2 | c.17241G>C p.E5747D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.303); called by muse, mutect2
- ALOX12 | c.1361G>A p.G454E | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARHGAP21 | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.315G>A p.M105I (on ENST00000359920 / NM_001130955.2; = p.M1? on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2
- ARID4B | c.2056G>C p.D686H | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- ASTN2 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL1 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1656G>C p.M552I | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP9A | c.2276G>T p.R759L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- BDP1 | c.4255C>G p.L1419V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- BMP1 | c.1136_1137del p.Y379Cfs*24 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- CASZ1 | c.3214C>T p.P1072S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CERK | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.026); called by muse, mutect2
- CNTN1 | c.2182G>C p.A728P | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.233); called by muse, mutect2
- COCH | c.1633G>A p.D545N (on ENST00000216361 / NM_001347720.1; = p.D480N on NM_004086.3) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP39A1 | c.1212C>G p.F404L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CYP4F8 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DEK | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- DLC1 | c.4135G>C p.E1379Q (on ENST00000276297 / NM_001348081.2; = p.E942Q on NM_006094.5) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- DNAH3 | c.5333A>G p.E1778G | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- E2F8 | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ELOVL7 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- ELP1 | c.3573G>T p.A1191= | Splice Region (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- FBXW12 | c.1114C>G p.L372V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- FCRL3 | c.1915A>C p.K639Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FNDC3B | c.3419G>T p.G1140V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAS6 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GCG | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GPR158 | c.806A>T p.Y269F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2
- GRIA3 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HMCES | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- IGF2BP1 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IGLC7 | c.125G>A p.W42* | Nonsense Mutation (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- IL17F | c.186C>G p.I62M | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- IL2RG | c.957G>C p.E319D | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ILRUN | c.775C>G p.Q259E (on ENST00000374023 / NM_024294.4; = p.Q193E on NM_022758.6) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IVL | c.1094T>A p.L365H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAG1 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.1102-1G>C p.X368_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- KDM6A | c.3631del p.I1211Ffs*10 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- KERA | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KIAA0825 | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- KLHL22 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- KNTC1 | c.2058G>T p.R686S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT6A | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGT1 | c.411_413del p.T138del (on ENST00000618282 / NM_001367916.1; = p.T170del on NM_032121.5) | In Frame Del (DEL) | VAF 28/90 reads (31%) | called by pindel, varscan2
- MAP3K14 | c.2427_2430del p.S809Rfs*15 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- MLXIP | c.1500del p.F501Lfs*8 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- MTR | c.2875C>G p.Q959E | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK11 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEO1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NEXN | c.1762C>A p.L588I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- NLN | c.1527+1G>A p.X509_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- NOC4L | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- NOTCH3 | c.4250G>C p.C1417S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE9A | c.502T>C p.F168L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- PIGN | c.2539G>C p.E847Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PLA2G4F | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2
- PLSCR1 | c.46A>C p.N16H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPFIA1 | c.2866-1G>C p.X956_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- PPP1R21 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PSKH2 | c.803C>G p.T268R | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2
- PTPN13 | c.3947C>G p.S1316* (on ENST00000411767 / NM_080683.3; = p.S1297* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.1446C>A p.D482E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIMS2 | c.4235C>G p.S1412C (on ENST00000666250 / NM_001348490.2; = p.S983C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RTN1 | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCUBE2 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SFI1 | c.2983C>A p.H995N (on ENST00000400288 / NM_001007467.3; = p.H964N on NM_014775.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- SLC6A20 | c.108G>C p.Q36H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCA2 | c.4198A>G p.R1400G | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SUSD2 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TESPA1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- TMEM241 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TMF1 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- TTPAL | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.672); called by muse, mutect2
- UAP1L1 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- UBE3A | c.1746C>G p.I582M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- UTP20 | c.2550C>G p.I850M | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2
- VANGL2 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFAT | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZKSCAN2 | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2
- ZMYM1 | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- ZNF428 | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2
- ZNF624 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF681 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ZNF707 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.042); called by muse, mutect2
- ZNF750 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ZNF790 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- ZNF91 | c.1304A>C p.K435T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); called by mutect2, varscan2
- ZNRD2 | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.275); called by muse, varscan2
- AGO1 | c.2118G>A p.Q706= | Silent (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4189C>T p.L1397= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4188C>T p.F1396= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1383G>A p.R461= (on ENST00000395184 / NM_001025616.3; = p.R368= on NM_031305.3) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs778915879; called by muse, mutect2, varscan2
- CADM4 | c.609C>T p.N203= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- CMTR1 | c.339G>A p.R113= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV65090271; called by muse, mutect2, varscan2
- DAGLA | c.840C>T p.L280= | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- ERGIC3 | c.204G>A p.L68= | Silent (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- FAM193A | c.2316G>A p.E772= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as rs1159968508; called by muse, mutect2
- FAM220A | c.369A>G p.E123= | Silent (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- FANCB | c.1503G>C p.L501= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- FMN2 | c.3234C>A p.P1078= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, varscan2
- GNA15 | c.951G>T p.T317= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99505502; called by muse, mutect2, varscan2
- GNPTG | c.501C>T p.L167= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs756686252, COSV50189984; called by muse, mutect2, varscan2
- GUSB | c.567G>C p.L189= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- HDLBP | c.2469G>A p.L823= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- HELZ2 | c.7008C>T p.V2336= (on ENST00000467148 / NM_001037335.2; = p.V1767= on NM_033405.3) | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- IGSF3 | c.693C>T p.L231= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- KRT16 | c.441G>T p.V147= | Silent (SNP) | VAF 24/198 reads (12%) | catalogued as COSV56969693; called by muse, mutect2, varscan2
- KRT8 | c.573C>T p.N191= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs202170959; called by muse, mutect2, varscan2
- LGALS3BP | c.477G>C p.V159= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV53166364; called by muse, mutect2, varscan2
- MAPK4 | c.1763G>A p.*588= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs746873598; called by muse, mutect2, varscan2
- MARF1 | c.2689C>T p.L897= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MDGA2 | c.1758C>A p.T586= (on ENST00000399232 / NM_001113498.2; = p.T288= on NM_182830.4) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100638106, COSV100638364; called by muse, mutect2, varscan2
- MGA | c.7800G>A p.P2600= (on ENST00000219905 / NM_001164273.1; = p.P2391= on NM_001080541.2) | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs372185993; called by muse, mutect2, varscan2
- MLXIPL | c.396C>T p.I132= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- MPZL2 | c.402G>A p.V134= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2
- MTIF2 | c.264A>G p.K88= | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2
- MYO1A | c.2844C>G p.L948= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV55654477; called by muse, mutect2, varscan2
- MYO3A | c.4479A>C p.P1493= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- NIN | c.4512G>A p.E1504= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- OPN1LW | c.699T>G p.A233= | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- OR1C1 | c.351G>C p.V117= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101376189, COSV68715967; called by muse, mutect2, varscan2
- OR2M2 | c.849C>T p.P283= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV62898787, COSV62899319; called by muse, mutect2
- PABPC1 | c.1014A>G p.V338= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs752973206; called by muse, varscan2
- PXMP2 | c.420C>T p.F140= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs201001554; called by muse, mutect2, varscan2
- RELN | c.8067C>T p.A2689= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs776667611; called by muse, mutect2, varscan2
- SEC23IP | c.2262C>T p.C754= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as rs758619932; called by muse, mutect2
- SLC6A2 | c.480C>T p.L160= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs768139475; called by muse, mutect2, varscan2
- SPPL3 | c.921G>A p.G307= | Silent (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- SV2B | c.1656G>A p.G552= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100370617, COSV100370725; called by mutect2, varscan2
- TEFM | c.192C>G p.L64= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- TMEM59 | c.24C>A p.L8= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- TOP1MT | c.1029C>T p.L343= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs1333928804; called by muse, mutect2, varscan2
- URB2 | c.804G>T p.T268= | Silent (SNP) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- VAC14 | c.1326C>T p.S442= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs760811310; called by muse, mutect2, varscan2
- VCAN | c.3918G>A p.A1306= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs768841073, COSV54104831; called by muse, mutect2, varscan2
- ZNF410 | c.888G>A p.L296= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- ZNRD2 | c.471C>G p.L157= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, varscan2
- AGAP7P | n.1208C>A | RNA (SNP) | VAF 59/319 reads (18%) | called by muse, mutect2, varscan2
- C7orf66 | n.332G>A | RNA (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- FARSB | c.-1C>T | 5'UTR (SNP) | VAF 15/46 reads (33%) | catalogued as rs1249794863; called by muse, mutect2, varscan2
- PARGP1 | n.2049C>T | RNA (SNP) | VAF 49/310 reads (16%) | called by muse, mutect2, varscan2
- PGM1 | c.247-5802G>C | Intron (SNP) | VAF 7/76 reads (9%) | catalogued as rs1279926648; called by muse, mutect2
- SLC48A1 | c.*165T>C | 3'UTR (SNP) | VAF 22/98 reads (22%) | catalogued as rs780184509; called by muse, mutect2, varscan2
- SSPOP | n.1452C>T | RNA (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
